Somatic mutation profile of tumor specimen MP2PRT-PAPNWT-TMP1-A (aliquot MP2PRT-PAPNWT-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPNWT, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.6 years (567 days).
Specimen MP2PRT-PAPNWT-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27c2955a-4656-4d1d-87fa-cb498ff3fba3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPNWT-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPNWT-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d1bd6df-437e-4272-af01-1192cc5cf184

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GREB1 | c.4385C>T p.A1462V | Missense Mutation (SNP) | VAF 73/284 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs376078784; called by muse, mutect2, varscan2
- TEK | c.2848C>T p.R950W | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1201741867; called by muse, mutect2, varscan2
- PAK3 | c.439G>C p.V147L (on ENST00000262836 / NM_001324328.2; = p.V132L on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/222 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.041); called by muse, mutect2
- SHROOM2 | c.4062C>T p.D1354= | Silent (SNP) | VAF 69/319 reads (22%) | catalogued as rs1054584376, COSV101099096; called by muse, mutect2, varscan2
- UROC1 | c.459T>A p.T153= | Silent (SNP) | VAF 16/298 reads (5%) | called by muse, mutect2
